Somatic mutation profile of tumor specimen 0DVXFJ from CCDI case PBCNDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,337 days).
Specimen 0DVXFJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca405b37-84d7-4b92-89a9-747f07587019.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b30c7ba2-9596-4f68-a3c2-92048400bd9c

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP6 | c.457+21C>T | Intron (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
